TCGA case TCGA-DQ-7588 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8a3fdb52-63ef-48d7-95ff-167829825eb9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Dead; Days to death: 427 days (1.2 years).

Diagnoses (4)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C14.8; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.0 years (24,106 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic N: NX; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 1; Lymph nodes tested: 30; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Cetuximab; Initial disease status: Recurrent Disease; Days to treatment start: 159 days; Days to treatment end: 215 days; Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 159 days; Days to treatment end: 215 days; Treatment dose: 6,400 cGy; Course number: 1; Number of fractions: 32; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Palliative; Days to treatment start: 379 days (1.0 years); Days to treatment end: 421 days (1.2 years); Number of cycles: 3; Treatment dose: 455 mg; Prescribed dose: 152; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gossypol; Treatment intent type: Palliative; Days to treatment start: 379 days (1.0 years); Days to treatment end: 421 days (1.2 years); Number of cycles: 3; Treatment dose: 480 mg; Prescribed dose: 80; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gossypol; Treatment intent type: Palliative; Days to treatment start: 421 days (1.2 years); Days to treatment end: 425 days (1.2 years); Number of cycles: 1; Treatment dose: 100 mg; Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
2. Prior malignancy of the prostate gland (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Mouth, NOS. Age at diagnosis: 66.2 years (24,185 days); Days to diagnosis: 79 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 106 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
4. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lymph nodes of head, face and neck. Age at diagnosis: 66.9 years (24,429 days); Days to diagnosis: 323 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (3 entries)
- Day 79 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mouth, NOS; Days to recurrence: 79 days.
- Day 323 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to recurrence: 323 days.
- Days to follow up: 427 days (1.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A: Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 45; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 2010.
- Alcohol history: Yes; Alcohol drinks per day: 10; Alcohol days per week: 4.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DQ-7588-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.4; Intermediate dimension: 0.3; Shortest dimension: 0.2.
  Slide TCGA-DQ-7588-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 10.
- Sample TCGA-DQ-7588-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-DQ-7588-10A, TCGA-DQ-7588-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Anatomic organ subdivision: Buccal Mucosa; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Lymphovascular invasion: No; Tobacco smoking history indicator: 4; Alcohol consumption frequency: 4.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: erbitux.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: AT-101.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Follow-up form 1: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event site: Oral Cavity; Treatment outcome first course: Persistent Disease; Treatment outcome at TCGA followup: Persistent Disease.
- Follow-up form 2: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event site: Cervical Lymph Nodes; Treatment outcome first course: Persistent Disease; Treatment outcome at TCGA followup: Persistent Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy prostate cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 427 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 427 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 79 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DQ-7588-01A-11D-2077-01): tumor purity 0.6, ploidy 3.42, whole-genome doublings 1.
